Somatic mutation profile of tumor specimen C3L-06960-58 (aliquot CPT0391970002) from CPTAC case C3L-06960, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 50.6 years (18,477 days).
Specimen C3L-06960-58: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d2be200-d163-47ec-b464-78ae999c9e9b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06960-50 (Buccal Cell Normal), aliquot CPT0391930002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e33361b5-3c87-4f4b-b60c-627c8a7e08e2

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 4, Silent 3, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 21/70 reads (30%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SCN9A | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 13/138 reads (9%) | catalogued as rs377543079, COSV57602874; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDC45 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 45/430 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as rs761996349; called by muse, mutect2, varscan2
- UTP20 | c.3851T>A p.I1284K | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as COSV99881974; called by muse, mutect2, varscan2
- ZC3H4 | c.1870A>G p.M624V | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.66); PolyPhen benign (0.103); catalogued as rs376177260; called by muse, mutect2, varscan2
- CDIP1 | c.92C>A p.S31Y | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- KNL1 | c.3118C>T p.Q1040* (on ENST00000346991 / NM_170589.5; = p.Q1014* on NM_144508.5) | Nonsense Mutation (SNP) | VAF 33/77 reads (43%) | called by muse, mutect2, varscan2
- COMMD8 | c.159C>T p.H53= | Silent (SNP) | VAF 30/108 reads (28%) | catalogued as rs756451793, COSV67500448; called by mutect2, varscan2
- PLD4 | c.396C>T p.S132= | Silent (SNP) | VAF 24/172 reads (14%) | catalogued as rs776782761, COSV101190492; called by muse, mutect2, varscan2
- SORCS2 | c.2484C>T p.Y828= | Silent (SNP) | VAF 57/379 reads (15%) | catalogued as rs774304661; called by muse, mutect2, varscan2
